TCGA case TCGA-CJ-5681 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2939c03a-6f3f-4f7b-b246-34361baadeb9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 44 years; Vital status: Dead; Days to death: 552 days (1.5 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 44.1 years (16,121 days); Year of diagnosis: 2003; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Recombinant Interleukin-2; Initial disease status: Progressive Disease; Days to treatment start: 105 days; Days to treatment end: 135 days; Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 165 days; Days to treatment end: 235 days; Number of cycles: 3; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 235 days; Days to treatment end: 318 days; Number of cycles: 4; Prescribed dose: 650; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Everolimus; Initial disease status: Progressive Disease; Days to treatment start: 305 days; Days to treatment end: 365 days (1.0 years); Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 385 days (1.1 years); Days to treatment end: 431 days (1.2 years); Treatment dose: 3,500 cGy; Course number: 1; Treatment anatomic sites: Distant Site.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 44.2 years (16,138 days); Days to diagnosis: 17 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 17 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 552 days (1.5 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Recurrence/Progression.

Molecular and laboratory tests
- Platelets: Normal.
- Hemoglobin: Low.
- Lactate Dehydrogenase: Elevated.
- Leukocytes: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-5681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.8; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-CJ-5681-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 10.
  Slide TCGA-CJ-5681-01A-01-TS1: Section location: Top; Percent tumor cells: 88; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 12; Percent stromal cells: 12.
- Sample TCGA-CJ-5681-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-5681-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 3.7; Intermediate dimension: 1; Shortest dimension: 1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: IL-2; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 3; Pharmaceutical therapy drug name: avastin; Therapy regimen: Progression.
- Drug treatment 3: Regimen number: 4; Pharmaceutical therapy drug name: RAD001; Therapy regimen: Progression.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 4: Regimen number: 2; Therapy regimen: Progression.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Performance status timing: At Recurrence/Progression Of Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 552 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 552 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 17 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CJ-5681-01A-11D-1530-01): tumor purity 0.84, ploidy 1.97, whole-genome doublings 0.
